FM case AD709 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/20bd8e3b-ea0d-4312-846c-9dceb332ae52

Male, 62.7 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the colon; metastasis. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
